Somatic mutation profile of tumor specimen d7b05dce-4362-4e8f-a77a-07dd74 (aliquot d7b05dce-4362-4e8f-a77a-07dd74_D6_1) from CPTAC case 11BR040, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.5 years (24,667 days).
Specimen d7b05dce-4362-4e8f-a77a-07dd74: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aea49839-1721-426d-89bb-ff51f9c8c591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4c5dd3bd-ff23-4f6e-9f10-82a33b (Blood Derived Normal), aliquot 4c5dd3bd-ff23-4f6e-9f10-82a33b_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85183bd1-c0cf-4522-82a9-40ff0490cba9

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 3, Splice Site 3, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 55/203 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62572203, COSV62573812; called by muse, mutect2, varscan2
- ATP4A | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs145767701, COSV52866100; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 64/332 reads (19%) | catalogued as rs763236375, COSV60515023; called by pindel, varscan2
- JAG2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 323/1109 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138503062; called by mutect2, varscan2
- RIMBP3 | c.3217T>C p.S1073P | Missense Mutation (SNP) | VAF 102/1584 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1253118228; called by muse, mutect2
- CTCF | c.1999+2_1999+3insTT p.X667_splice | Splice Site (INS) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- DLAT | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2
- KMT2C | c.4051dup p.R1351Kfs*4 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, varscan2
- LMNTD2 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- MROH9 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MYC | c.280T>C p.S94P (on ENST00000377970; = p.S109P on NM_002467.6) | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRH2 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- RYR3 | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SSUH2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- TAPT1 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.245); called by muse, mutect2
- ZNF618 | c.2845C>G p.L949V (on ENST00000374126 / NM_001318042.2; = p.L856V on NM_133374.2) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- CADPS | c.3486C>T p.Y1162= | Silent (SNP) | VAF 45/204 reads (22%) | called by muse, mutect2, varscan2
- CHD6 | c.3474G>A p.L1158= | Silent (SNP) | VAF 77/426 reads (18%) | called by muse, mutect2, varscan2
- ZNF526 | c.198T>C p.Y66= | Silent (SNP) | VAF 48/1224 reads (4%) | called by muse, mutect2
- ZSWIM5 | c.861A>G p.L287= | Silent (SNP) | VAF 54/184 reads (29%) | called by muse, mutect2, varscan2
- ZYG11A | c.1434T>C p.H478= | Silent (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501587 C>T | 5'Flank (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- CA14 | c.76+161del | Intron (DEL) | VAF 36/150 reads (24%) | called by mutect2, varscan2
- HOXA1 | c.*34C>T | 3'UTR (SNP) | VAF 66/198 reads (33%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-297G>T | Intron (SNP) | VAF 34/396 reads (9%) | called by muse, mutect2
- OR5P1P | n.676G>A | RNA (SNP) | VAF 20/371 reads (5%) | called by muse, mutect2
- PAXX | c.180+11G>T | Intron (SNP) | VAF 34/142 reads (24%) | catalogued as COSV100860479; called by muse, mutect2, varscan2
